Somatic mutation profile of tumor specimen TCGA-97-7941-01A (aliquot TCGA-97-7941-01A-11D-2184-08) from TCGA case TCGA-97-7941, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 72.0 years (26,298 days).
Specimen TCGA-97-7941-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e331344f-d81a-4abc-a4e6-918566451b65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-97-7941-10A (Blood Derived Normal), aliquot TCGA-97-7941-10A-01D-2184-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db36d7f8-cde3-4218-bcc7-ab991f76306c

The open-access MAF lists 95 somatic variants for this specimen: 71 protein-altering or splice-affecting, 23 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 23, Nonsense Mutation 6, Frame Shift Del 4, In Frame Del 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 11/38 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NFE2L2 | c.236A>T p.E79V | Missense Mutation (SNP) | VAF 14/73 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057519923, COSV67960135, COSV67960407, COSV67962953; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1157G>T p.G386V | Missense Mutation (SNP) | VAF 23/112 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912580, CM021284, COSV61684421, COSV61688134, COSV61692671; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABT1 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs782519551, COSV51291161, COSV51291336; called by muse, mutect2, varscan2
- AFF4 | c.1988C>T p.S663L | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as COSV54795004; called by muse, mutect2, varscan2
- AHCTF1 | c.4897G>T p.G1633C (on ENST00000366508; = p.G1607C on NM_015446.5) | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58250621; called by muse, mutect2, varscan2
- AIDA | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV60664026; called by mutect2, varscan2
- AKAP4 | c.148C>A p.L50M | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV62074551; called by muse, mutect2
- ALG10 | c.726G>T p.M242I | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV56792750; called by muse, mutect2, varscan2
- ARMC3 | c.55C>A p.P19T | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV53061809; called by muse, mutect2, varscan2
- BZW2 | c.1196A>G p.K399R | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as COSV51755353; called by muse, mutect2, varscan2
- C10orf90 | c.1424G>C p.S475T | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.152); catalogued as COSV52955948; called by muse, mutect2, varscan2
- CACNA1F | c.4757C>T p.T1586I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV59904656; called by muse, mutect2, varscan2
- CACNA2D3 | c.1994G>A p.R665H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs758578883, COSV55541845; called by muse, mutect2, varscan2
- CCDC86 | c.868G>T p.E290* | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | catalogued as COSV57126246, COSV99920321; called by muse, mutect2, varscan2
- CDHR5 | c.1253C>T p.T418I | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV57643224; called by muse, mutect2, varscan2
- CEMIP2 | c.538C>A p.L180M | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV65487415; called by muse, mutect2, varscan2
- CFAP61 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.311); catalogued as COSV55630743; called by muse, mutect2, varscan2
- CR2 | c.749G>A p.G250D | Missense Mutation (SNP) | VAF 44/258 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1173666662, COSV65507793; called by muse, mutect2, varscan2
- CRX | c.550C>A p.P184T | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.096); catalogued as COSV55758399; called by muse, mutect2, varscan2
- CYP2A6 | c.1402C>A p.P468T | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV56535432; called by muse, mutect2
- DOCK11 | c.1334C>A p.S445* | Nonsense Mutation (SNP) | VAF 23/100 reads (23%) | catalogued as COSV52239547, COSV99353144; called by muse, mutect2, varscan2
- FAM47B | c.1129C>A p.P377T | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.736); catalogued as rs372229852, COSV61454110; called by muse, mutect2, varscan2
- FAT2 | c.9035C>A p.S3012* | Nonsense Mutation (SNP) | VAF 4/37 reads (11%) | catalogued as COSV55820439; called by muse, mutect2, varscan2
- GRID1 | c.910C>G p.L304V | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.298); catalogued as COSV100024735, COSV60024216, COSV60030402; called by muse, mutect2, varscan2
- GRM1 | c.563C>A p.T188K | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV51154856; called by muse, mutect2
- HYAL3 | c.70C>A p.P24T | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.091); catalogued as COSV56497733; called by muse, mutect2, varscan2
- IGKV3D-11 | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 18/85 reads (21%) | catalogued as rs371297630; called by muse, mutect2, varscan2
- IL12B | c.874G>T p.D292Y | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as rs150030340; called by muse, mutect2, varscan2
- JAK2 | c.682C>T p.R228* | Nonsense Mutation (SNP) | VAF 15/182 reads (8%) | catalogued as rs772744665, COSV67570332, COSV67685252; called by muse, mutect2
- KAT6A | c.3379C>T p.L1127F | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1175450198, COSV55903846, COSV99705945; called by muse, mutect2
- KDM2B | c.1238A>T p.E413V | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.154); catalogued as COSV65641085; called by muse, mutect2, varscan2
- KHDC3L | c.356G>C p.G119A | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.018); catalogued as COSV64863330; called by muse, mutect2, varscan2
- LEPROT | c.94G>T p.V32F | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.597); catalogued as COSV60756051; called by muse, mutect2, varscan2
- LTF | c.1488C>A p.F496L | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV51608296; called by muse, mutect2
- MFAP3L | c.634A>T p.T212S | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64372255; called by muse, mutect2, varscan2
- MOB1B | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1392541792, COSV58673920; called by muse, mutect2, varscan2
- MRAP | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.015); catalogued as COSV57936988; called by muse, mutect2, varscan2
- MRGBP | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV100978310; called by muse, mutect2, varscan2
- MYH8 | c.5648G>T p.R1883I | Missense Mutation (SNP) | VAF 51/218 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV67965762; called by muse, mutect2, varscan2
- MYOCD | c.215G>T p.C72F | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV58503088; called by muse, mutect2, varscan2
- PCDHB3 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 12/153 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.124); catalogued as rs1031355369, COSV50576610; called by muse, mutect2
- PKLR | c.902T>C p.L301P | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61361297; called by muse, mutect2, varscan2
- RANBP2 | c.245G>A p.C82Y | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99313416; called by muse, mutect2, varscan2
- RELN | c.8869G>A p.G2957S | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV59004311; called by muse, mutect2
- RNF213 | c.7483A>G p.I2495V | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.044); catalogued as rs780710467, COSV60398433, COSV60401268; called by muse, mutect2, varscan2
- RPS6KA6 | c.930G>T p.R310S | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53118514, COSV99424790; called by muse, mutect2, varscan2
- SCARA5 | c.241+1G>C p.X81_splice | Splice Site (SNP) | VAF 12/50 reads (24%) | catalogued as COSV57277557; called by muse, mutect2, varscan2
- SCML2 | c.1360C>T p.H454Y | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV52621268; called by muse, mutect2
- SCN10A | c.3359T>A p.I1120N | Missense Mutation (SNP) | VAF 37/264 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as COSV71861558; called by muse, mutect2, varscan2
- SETD2 | c.6208C>T p.Q2070* | Nonsense Mutation (SNP) | VAF 32/219 reads (15%) | catalogued as COSV57438524; called by muse, mutect2, varscan2
- SETD2 | c.4502G>C p.C1501S | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57430129, COSV57441923; called by muse, mutect2, varscan2
- SLC30A10 | c.1264C>A p.L422M | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as COSV100751471, COSV100751619, COSV63071709; called by muse, mutect2, varscan2
- SPAG6 | c.554G>T p.R185M | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV57620731; called by muse, mutect2, varscan2
- SPEF2 | c.4666G>C p.E1556Q | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.274); catalogued as COSV57429368; called by muse, mutect2, varscan2
- SPHKAP | c.4747C>T p.L1583F (on ENST00000392056 / NM_001142644.2; = p.L1554F on NM_030623.3) | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.148); catalogued as COSV60880534, COSV60898791; called by muse, mutect2
- TAOK2 | c.967G>T p.G323C | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54236212; called by muse, mutect2, varscan2
- TEX101 | c.366G>T p.Q122H (on ENST00000598265 / NM_001130011.3; = p.Q140H on NM_031451.4) | Missense Mutation (SNP) | VAF 44/267 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.531); catalogued as COSV53661982; called by muse, mutect2, varscan2
- TEX264 | c.337G>T p.D113Y | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV58134510; called by muse, mutect2, varscan2
- TMEM208 | c.205C>T p.H69Y | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs367799210; called by muse, mutect2, varscan2
- UNC5C | c.1582C>A p.P528T | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV71660534; called by muse, mutect2, varscan2
- VEGFC | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54598574; called by muse, mutect2, varscan2
- VN1R1 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.356); catalogued as COSV58091114; called by muse, mutect2
- ZBTB49 | c.2170G>T p.G724C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV61925136; called by muse, mutect2, varscan2
- CHD7 | c.8891A>G p.K2964R | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.899); called by muse, mutect2
- CLOCK | c.1301_1313del p.S434* | Frame Shift Del (DEL) | VAF 11/79 reads (14%) | called by mutect2, pindel, varscan2
- FBXO22 | c.1191_1194del p.H398Wfs*8 | Frame Shift Del (DEL) | VAF 10/88 reads (11%) | called by mutect2, pindel, varscan2
- FSTL5 | c.1729del p.A577Pfs*37 | Frame Shift Del (DEL) | VAF 13/88 reads (15%) | called by mutect2, pindel, varscan2
- LONP2 | c.2153del p.G718Efs*31 | Frame Shift Del (DEL) | VAF 13/85 reads (15%) | called by mutect2, pindel
- MRC1 | c.2062G>A p.A688T | Missense Mutation (SNP) | VAF 26/296 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- WWC1 | c.2290_2295del p.Q764_I765del | In Frame Del (DEL) | VAF 8/76 reads (11%) | called by pindel, varscan2
- CCDC172 | c.687T>C p.D229= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as rs1168789419, COSV60937925; called by muse, mutect2, varscan2
- CD244 | c.990G>A p.K330= (on ENST00000368033 / NM_001166663.2; = p.K325= on NM_016382.4) | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as COSV54434421; called by muse, mutect2
- CDH4 | c.2217C>T p.L739= | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as rs1457613687, COSV64655833; called by muse, mutect2, varscan2
- FN1 | c.432G>T p.G144= | Silent (SNP) | VAF 23/124 reads (19%) | catalogued as COSV60553877; called by muse, mutect2, varscan2
- FZD9 | c.1401C>A p.V467= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV59991465; called by muse, mutect2, varscan2
- IFT172 | c.591G>T p.P197= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV53134159; called by muse, mutect2
- IGHV3-7 | c.117C>G p.L39= | Silent (SNP) | VAF 24/214 reads (11%) | catalogued as rs375467224; called by muse, mutect2, varscan2
- KATNA1 | c.402C>T p.V134= | Silent (SNP) | VAF 8/109 reads (7%) | catalogued as rs1195199829, COSV59502463; called by muse, mutect2
- LDHA | c.54C>A p.T18= | Silent (SNP) | VAF 12/105 reads (11%) | catalogued as COSV57040351; called by muse, mutect2, varscan2
- MAB21L3 | c.1014C>A p.T338= | Silent (SNP) | VAF 7/185 reads (4%) | catalogued as COSV65673927; called by muse, mutect2
- MRPL53 | c.225T>A p.I75= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs1374693627, COSV50688604; called by muse, mutect2, varscan2
- OR8D4 | c.378C>A p.I126= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV58429938, COSV58430409; called by muse, mutect2, varscan2
- PCDHB13 | c.945C>A p.S315= | Silent (SNP) | VAF 15/137 reads (11%) | catalogued as rs782762792, COSV53396971, COSV53400037; called by muse, mutect2
- PCDHB16 | c.1371C>A p.T457= | Silent (SNP) | VAF 39/227 reads (17%) | catalogued as rs1378915437, COSV53362874; called by muse, mutect2, varscan2
- PCNX3 | c.3255A>G p.A1085= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV63137013; called by muse, mutect2, varscan2
- PTK2B | c.921C>T p.S307= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV57757337; called by muse, varscan2
- SCN1A | c.1701G>A p.R567= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as COSV57671545; called by muse, mutect2, varscan2
- SEMA3C | c.2034C>T p.T678= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as COSV54847178; called by muse, mutect2, varscan2
- SIDT2 | c.1926C>T p.I642= | Silent (SNP) | VAF 9/148 reads (6%) | catalogued as COSV54057223; called by muse, mutect2
- SPEN | c.5829G>A p.A1943= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as rs751161622, COSV65362622; called by muse, mutect2, varscan2
- SYMPK | c.3546G>T p.P1182= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV55571603, COSV55572087; called by muse, mutect2, varscan2
- TBL2 | c.384C>T p.R128= | Silent (SNP) | VAF 20/115 reads (17%) | catalogued as COSV59787170; called by muse, mutect2, varscan2
- TPSD1 | c.240G>T p.A80= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as rs569303909, COSV52975952; called by muse, mutect2, varscan2
- MROH8 | c.370+2454A>G | Intron (SNP) | VAF 5/12 reads (42%) | catalogued as COSV54116546; called by muse, mutect2, varscan2
